Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A231, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A231-01A (Primary Tumor).

[page 1 of 5]
HPV/A Discrepancy		☒
Discrepancy/Secondary Primary		☒
	for 4/8/11	

Specimen Description

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

*****Clinical History*****
Thyroid cancer

1CB-0.3
carcinoma, papillary thyroid 8260/3
Site thyroid, NOS 673.9 for 4/8/11

*****Final Pathologic Diagnosis*****

- A. Lymph node, anterior right neck:
- Metastatic papillary thyroid carcinoma in one lymph node (1/1)
- B. Soft tissue, right inferior neck:
Benign lymph node with extensive brown pigment deposition, consistent with hemosiderin (0/1); no parathyroid tissue is identified
- C. Right thyroid lobe:
- Papillary thyroid carcinoma (See SYNOPTIC REPORT)
- Metastatic papillary thyroid carcinoma in seven of seven lymph nodes (7/7)
- D. Right anterior Level III lymph nodes:
- Metastatic papillary thyroid carcinoma in two of two lymph nodes (2/2)
- E. Right central neck tissue:
- One benign lymph node (0/1)
- F. Right Level III and IV lymph nodes:
- Metastatic papillary thyroid carcinoma in five of fifteen lymph nodes (5/15)
- G. Soft tissue, right inferior neck:
- Portions of a lymph node with extensive brown pigment deposition, consistent with hemosiderin (0/1); no parathyroid tissue is identified
- H. Left thyroid lobe:
- Nodular goiter with focal chronic inflammation
- One benign lymph node (0/1)
- I. Superior central lymph nodes:
- Metastatic papillary thyroid carcinoma in one lymph node (1/1)

[page 2 of 5]
Sex:M

Print this Page

Specimen Description

Surgical Pathology Report

Patient Name
Accession #
Med. Rec #:
Submitting

*****Clinical History*****
Thyroid cancer

*****Final Pathologic Diagnosis*****

- A. Lymph node, anterior right neck:
- Metastatic papillary thyroid carcinoma in one lymph node (1/1)
- B. Soft tissue, right inferior neck:
- Benign lymph node with extensive brown pigment deposition, consistent with hemosiderin (0/1); no parathyroid tissue is identified
- C. Right thyroid lobe:
- Papillary thyroid carcinoma (See SYNOPSIS REPORT)
- Metastatic papillary thyroid carcinoma in seven of seven lymph nodes (7/7)
- D. Right anterior Level III lymph nodes:
- Metastatic papillary thyroid carcinoma in two of two lymph nodes (2/2)
- E. Right central neck tissue:
- One benign lymph node (0/1)
- F. Right Level III and IV lymph nodes:
- Metastatic papillary thyroid carcinoma in five of fifteen lymph nodes (5/15)
- G. Soft tissue, right inferior neck:
- Portions of a lymph node with extensive brown pigment deposition, consistent with hemosiderin (0/1); no parathyroid tissue is identified
- H. Left thyroid lobe:
- Nodular goiter with focal chronic inflammation
- One benign lymph node (0/1)
- I. Superior central lymph nodes:
- Metastatic papillary thyroid carcinoma in one lymph node (1/1)

[page 3 of 5]
*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: Total thyroidectomy

Tumor location: Right thyroid

Tumor size: 9.4 cm

Histologic type: Papillary thyroid carcinoma

Tumor grade: Grade 2 of 3

Lymphatic/vascular invasion: positive

Capsular invasion: Negative

Tumor extent:

Confined to the thyroid: yes

Multifocal: negative

Invasion of thyroid cartilage or hyoid bone: Negative

Infiltration of adjacent structures: Negative

Margins:

For partial or subtotal resection: uninvolved

Lymph nodes:

Total number examined: 31

Sites/laterality: Right side and superior central

Number positive: 16

Number negative: 15

Extranodal extension: negative

Additional pathologic findings: nodular goiter

Special studies: none

pTNM: pT3 pN1b pMx

Comments: The findings from the previous FNA have been noted

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists Protocols and the AJCC Cancer Staging Manual, 7th edition, 2010, for the reporting of cancer specimens.

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Anterior lymph node right neck: (FROZEN SECTION PERFORMED)
- One lymph node with metastatic papillary thyroid carcinoma.

BF1. Possible right inferior parathyroid: (FROZEN SECTION PERFORMED)
- Not parathyroid.

Examining pathologist: [REDACTED]

*****SPECIMEN(S) RECEIVED:*****

A: Lymph node, excision

[REDACTED]

[page 4 of 5]
B: Parathyroid gland, BX
C: Thyroid resection total or lobe
D: Lymph node, dissection
E: Lymph node, dissection
F: Lymph node, dissection
G: Parathyroid gland, BX
H: Thyroid resection total or lobe
I: Lymph node, dissection

*****GROSS DESCRIPTION:*****

The specimens are received in nine properly labeled containers with the patient's name and accession number, two of which are submitted for frozen section.

A. The specimen is designated "anterior lymph node right neck" and consists of a 1.7 x 1.2 x 1.0 cm aggregate of soft tissue in which there is a 1.3 x 1.0 x 0.6 cm lymph node. The specimen is resubmitted as received from frozen section in cassette AF1. TE 1

B. The specimen is designated "possible right inferior parathyroid" and consists of a 0.4 x 0.2 x 0.2 cm piece of soft tissue. The specimen is resubmitted as received from frozen section in cassette BF1. TE 1

C. The specimen is designated "right thyroid lobe" and consists of a 317.6 gram hemithyroidectomy that is 13.4 cm from superior to inferior, 9.4 cm from medial to lateral and 6.5 cm in the anteroposterior dimension. The outer surface of the hemithyroid is diffusely nodular and numerous grossly positive lymph nodes are identified in the perithyroidal soft tissue. The isthmus resection edge is inked orange and the outer surface of the specimen is inked blue. The cut surface of the mass is solid tan-white and has foci of both hemorrhage and necrosis. The greatest dimension of the mass is 9.4 cm. The mass diffusely approaches the inked outer surface of the thyroid. In the perithyroidal soft tissue, seven lymph nodes are identified, six of which are grossly positive for tumor. The largest grossly positive lymph node is 2.5 cm in greatest dimension. (

Summary of Cassettes: C1-2, isthmus resection edge, perpendicular; C3-6, representative sections of mass to inked outer surface; C7, necrotic and hemorrhagic portion of mass to inked outer surface; C8, one lymph node; C9, representative section of the largest grossly positive lymph node; C10, representative sections of three grossly positive lymph nodes; C11, representative sections of two grossly positive lymph nodes

D. The specimen is designated "right anterior level 3 lymph nodes" and consists of a 4.7 x 2.3 x 1.0 cm aggregate of tan-yellow soft tissue that contains two lymph nodes that are 2.9 x 1.5 x 1.0 and 2.5 x 1.3 x 1.0 cm respectively. The lymph nodes are grossly positive for tumor involvement (confirmed by touch preparation); one representative section of each lymph node is submitted for microscopic examination. (

Summary of Cassettes: D1, representative section of one grossly positive lymph node; D2, representative section of second grossly positive lymph node

Note: Each grossly positive lymph node is submitted in its plane of greatest dimension.

[page 5 of 5]
E. The specimen is designated "right central neck tissue" and consists of one sheet of tan-yellow soft tissue that is 4.2 x 3.5 x 0.4 cm. No lymph nodes are grossly identified. The entire specimen is submitted for microscopic examination. TE 2

F. The specimen is designated "right level 3 and 4 lymph nodes" and consists of an unoriented piece of soft yellow adipose tissue that is 6.2 x 5.7 x 1.9 cm. Multiple possible lymph nodes are identified that range from 0.2 to 1.8 cm in greatest dimension. Only adipose tissue remains in the container. RS 4

Summary of Cassettes: F1, six possible lymph nodes; F2, five possible lymph nodes; F3, three possible lymph nodes; F4, one possible lymph node, bisected

G. The specimen is designated "possible right inferior parathyroid" and consists of a less than 0.05 gram aggregate of red-brown soft tissue that is 0.7 x 0.3 x 0.2 cm. The specimen is submitted in its entirety for microscopic examination in cassette G1. TE 1

H. The specimen is designated "left thyroid lobe" and consists of an 11.0 gram hemithyroidectomy that is 5.4 cm from superior to inferior, 3.6 cm from medial to lateral and 1.3 cm in the anteroposterior dimension. The isthmic resection margin is inked orange and the outer surface of the thyroid is inked blue. The specimen is serially sectioned to reveal homogeneous beefy red parenchyma with no focal masses or lesions. RS 4

Summary of Cassettes: H1, isthmic resection edge, shaved; H2-4, representative sections of left thyroid lobe

I. The specimen is designated "superior central lymph nodes" and consists of one piece of tan-white soft tissue that is 2.4 x 1.4 x 0.8 cm. Two firm possible lymph nodes are identified that are 0.4 and 1.4 cm in greatest dimension respectively. TE 2

Summary of Cassettes: I1, one possible lymph node; I2, one possible lymph node, bisected

Lab Use Only: [REDACTED]

Gross description by: [REDACTED]

Source: NCI Genomic Data Commons file 321b328c-bc4c-4d41-9440-abf757aa768d (TCGA-FE-A231.8B8522CD-C9E7-4762-99F9-D597B35ABF03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).